Somatic mutation profile of tumor specimen TCGA-05-4427-01A (aliquot TCGA-05-4427-01A-21D-1855-08) from TCGA case TCGA-05-4427, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.4 years (23,893 days).
Specimen TCGA-05-4427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 571ab7df-ee67-4c91-b06d-935a14b5baab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4427-10A (Blood Derived Normal), aliquot TCGA-05-4427-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13ce267-8b9f-419d-92d1-4e38dfc006b2

The open-access MAF lists 1,074 somatic variants for this specimen: 851 protein-altering or splice-affecting, 207 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 730, Silent 207, Nonsense Mutation 63, Frame Shift Del 24, Splice Site 23, RNA 8, Splice Region 7, Intron 7, Frame Shift Ins 3, 3'Flank 1, In Frame Del 1.

Variants (750 of 1,074; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908527, CM056287, CM970064, COSV56754708; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>G p.S257W | Missense Mutation (SNP) | VAF 39/118 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4308G>A p.W1436* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV66067610; called by muse, mutect2, varscan2
- ABCB11 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV55594029; called by muse, mutect2, varscan2
- ABCC11 | c.1624G>T p.V542F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62324042; called by muse, mutect2
- ABCC11 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV62324048; called by muse, mutect2, varscan2
- ABCD2 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58052616; called by muse, mutect2, varscan2
- ABI3BP | c.1499C>A p.P500Q | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV52540615; called by muse, mutect2, varscan2
- AC126283.2 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67099036; called by muse, mutect2, varscan2
- ACAP2 | c.2014G>C p.V672L | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV58753071; called by muse, mutect2, varscan2
- ACCS | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV55458937; called by muse, mutect2, varscan2
- ADAM33 | c.2017C>G p.P673A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1471965150, COSV62935379; called by muse, mutect2, varscan2
- ADAM33 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756959212, COSV62935388; called by muse, mutect2, varscan2
- ADAMTS15 | c.2480G>T p.S827I | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV54507158; called by muse, mutect2, varscan2
- ADAMTS18 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs142855321; called by muse, mutect2, varscan2
- ADAMTS2 | c.2863C>A p.H955N | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as COSV52380074; called by muse, mutect2, varscan2
- ADAMTS20 | c.3887A>G p.N1296S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.611); catalogued as COSV101166417, COSV67133903; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV54454421; called by mutect2, varscan2
- ADGRB3 | c.3254C>T p.T1085I | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV53249918; called by muse, mutect2, varscan2
- ADGRG4 | c.5662G>A p.A1888T | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54959721; called by muse, varscan2
- ADGRL2 | c.3230G>C p.G1077A (on ENST00000370717 / NM_001366005.1; = p.G1064A on NM_012302.4) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV54673625; called by muse, mutect2
- ADGRL4 | c.448T>A p.S150T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV66062440; called by muse, mutect2
- ADGRV1 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1425050498, COSV67988242, COSV67994975; called by muse, mutect2, varscan2
- ADGRV1 | c.2347A>G p.R783G | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1242060957, COSV67988245; called by muse, mutect2, varscan2
- AFM | c.676del p.A226Hfs*3 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as COSV56919129; called by mutect2, pindel, varscan2
- AGRN | c.2588C>T p.T863M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766149292, COSV65070431; called by muse, mutect2, varscan2
- AKAP9 | c.11496A>T p.E3832D (on ENST00000359028; = p.E3808D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as COSV50152318; called by muse, mutect2, varscan2
- ALB | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55739218, COSV55741955; called by muse, mutect2, varscan2
- ALG1L | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61076085; called by muse, mutect2
- ALPK1 | c.3482A>G p.Y1161C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763178615, COSV51586754; called by muse, varscan2
- ALPK2 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64494059; called by muse, mutect2, varscan2
- AMOT | c.1259A>T p.Y420F (on ENST00000371959 / NM_001113490.1; = p.Y11F on NM_133265.3) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as COSV59064972; called by muse, mutect2, varscan2
- ANKLE2 | c.348G>T p.R116S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV61710087; called by muse, mutect2
- ANKRD12 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50830652; called by muse, mutect2, varscan2
- ANKRD17 | c.5545G>T p.A1849S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV58222871; called by muse, mutect2, varscan2
- ANO6 | c.1358C>A p.T453N | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs1446727751, COSV57663029; called by muse, mutect2, varscan2
- AOC1 | c.2108del p.P703Qfs*12 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV62870693; called by mutect2, pindel, varscan2
- APOB | c.13246G>C p.V4416L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV51940740; called by muse, mutect2, varscan2
- APOBEC1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs370589831; called by muse, mutect2, varscan2
- AR | c.2333A>C p.K778T | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV65957933, COSV65958597; called by muse, mutect2
- ARHGAP22 | c.2036A>G p.E679G | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV50951127; called by muse, mutect2
- ARHGAP39 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1235988824, COSV52769171; called by muse, mutect2, varscan2
- ARHGAP44 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781001928, COSV52396011; called by mutect2, varscan2
- ARHGEF4 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV58124316; called by muse, mutect2, varscan2
- ARID1A | c.1165A>C p.K389Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV61380820, COSV61389280; called by muse, mutect2
- ARMC3 | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV53063288, COSV53068108; called by muse, mutect2, varscan2
- ARNT2 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); catalogued as COSV57587033; called by muse, mutect2, varscan2
- ARPP21 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV51795203, COSV51800822, COSV51805657; called by muse, varscan2
- ASAP1 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63050470; called by muse, mutect2
- ASB9 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV66851874; called by muse, mutect2, varscan2
- ASCC3 | c.5431G>T p.E1811* | Nonsense Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as COSV100976841, COSV64973769; called by muse, mutect2, varscan2
- ASPM | c.7691A>G p.Y2564C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1356417425, COSV54132526, COSV99660413; called by muse, mutect2, varscan2
- ASTN2 | c.3678G>T p.M1226I (on ENST00000313400 / NM_001365069.1; = p.M1175I on NM_014010.5) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV56008037, COSV99940894; called by muse, mutect2, varscan2
- ATL1 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63296750; called by muse, mutect2
- ATL2 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV60050106, COSV60053325; called by muse, mutect2, varscan2
- ATP10B | c.121A>G p.N41D | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as COSV58779324; called by muse, mutect2, varscan2
- ATP11B | c.2390C>G p.P797R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60029958, COSV60031552; called by mutect2, varscan2
- ATP12A | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54518432; called by muse, mutect2, varscan2
- ATP13A5 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs751305381, COSV60870997; called by muse, mutect2, varscan2
- ATP2A3 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.203); catalogued as rs373653499; called by muse, mutect2
- ATP7B | c.1668G>T p.M556I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99666059, COSV99666894; called by muse, mutect2, varscan2
- ATP7B | c.1667T>A p.M556K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99666896; called by muse, mutect2, varscan2
- ATRNL1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61807546; called by muse, mutect2, varscan2
- ATRX | c.5188G>A p.A1730T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV64878600; called by muse, mutect2, varscan2
- BACH1 | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV54521925, COSV99728626; called by muse, mutect2, varscan2
- BAHD1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV69084172; called by muse, mutect2, varscan2
- BCOR | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60710657; called by muse, mutect2, varscan2
- BIRC6 | c.8137A>T p.N2713Y | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV70201483; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4889T>C p.L1630P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.27); catalogued as COSV63245568; called by muse, mutect2, varscan2
- BMP10 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV54895769; called by muse, mutect2, varscan2
- BNC2 | c.1502T>C p.M501T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1474130756, COSV66150188; called by muse, mutect2, varscan2
- BOC | c.1087del p.L363Sfs*41 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV56349892; called by mutect2, pindel, varscan2
- BOD1L1 | c.4796G>A p.G1599E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50020939; called by muse, mutect2
- BOD1L1 | c.1361A>G p.Q454R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs775591325, COSV50021069; called by mutect2, varscan2
- BPNT1 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV100435571, COSV59040363; called by muse, mutect2, varscan2
- BRCA2 | c.8472A>T p.R2824S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66456257; called by mutect2, varscan2
- BSCL2 | c.834C>G p.D278E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54016328; called by muse, mutect2, varscan2
- BTRC | c.1634C>T p.T545I (on ENST00000370187 / NM_033637.4; = p.T509I on NM_003939.5) | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64579879; called by muse, mutect2, varscan2
- C15orf39 | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100641450; called by muse, mutect2
- C20orf27 | c.385G>T p.G129C (on ENST00000379772 / NM_001258429.2; = p.G154C on NM_001039140.3) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV53924392; called by muse, mutect2, varscan2
- C3orf38 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.036); catalogued as COSV59628384; called by muse, mutect2, varscan2
- C6 | c.168C>A p.Y56* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54712266; called by muse, mutect2, varscan2
- CA4 | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958489; called by muse, mutect2, varscan2
- CADPS | c.1161C>A p.N387K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.986); catalogued as COSV51886970; called by muse, mutect2, varscan2
- CALB1 | c.342C>G p.H114Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV55368169, COSV99618561; called by mutect2, varscan2
- CALCR | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1357063215, COSV64009220; called by muse, mutect2, varscan2
- CAMSAP2 | c.1713G>T p.Q571H (on ENST00000236925 / NM_001297707.2; = p.Q560H on NM_203459.3) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV52672820; called by muse, mutect2, varscan2
- CAPN11 | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as COSV67238114; called by muse, mutect2, varscan2
- CAPNS2 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100045239; called by muse, mutect2, varscan2
- CASP2 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV60082598; called by muse, mutect2, varscan2
- CASR | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs764023058, COSV56133705, COSV99948869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58424629; called by muse, mutect2
- CCDC15 | c.1752T>G p.D584E | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.114); catalogued as COSV61082489; called by muse, mutect2, varscan2
- CCDC50 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66668591; called by muse, mutect2, varscan2
- CCDC88C | c.3278A>C p.Q1093P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66239131; called by muse, mutect2, varscan2
- CCHCR1 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV66184113; called by muse, mutect2, varscan2
- CCT8L2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV63462903; called by muse, mutect2, varscan2
- CD22 | c.1573G>T p.V525F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV50056234; called by muse, mutect2, varscan2
- CD44 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53529937; called by muse, mutect2, varscan2
- CDC20 | c.1409G>A p.W470* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV60522337; called by muse, mutect2, varscan2
- CDC73 | c.1324G>T p.V442F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100813910, COSV66467919; called by muse, mutect2, varscan2
- CDH10 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV52585384; called by muse, mutect2, varscan2
- CDH10 | c.10C>A p.H4N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100052871; called by muse, mutect2, varscan2
- CDH13 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV51833456; called by muse, mutect2, varscan2
- CDH18 | c.2168C>A p.A723E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56924786, COSV56932951; called by muse, mutect2, varscan2
- CDH6 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV54072391; called by muse, mutect2
- CDH6 | c.1957A>T p.R653* | Nonsense Mutation (SNP) | VAF 34/85 reads (40%) | catalogued as COSV54072404; called by muse, mutect2, varscan2
- CDHR3 | c.2218A>G p.R740G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV58418622; called by muse, mutect2
- CDKN1A | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 127/184 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV55189723; called by muse, mutect2, varscan2
- CEACAM21 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.413); catalogued as COSV99494813; called by muse, mutect2
- CEL | c.656G>C p.G219A (on ENST00000673714; = p.G216A on NM_001807.6) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV60828161; called by muse, mutect2
- CELF2 | c.428G>T p.C143F (on ENST00000416382 / NM_001025077.3; = p.C150F on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.73); catalogued as COSV100258193; called by muse, mutect2, varscan2
- CENPI | c.1923T>A p.N641K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54503647; called by muse, mutect2, varscan2
- CES5A | c.551+1G>C p.X184_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV51866498, COSV51867652; called by muse, mutect2, varscan2
- CFAP46 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.497); catalogued as COSV63952175, COSV63955036; called by muse, mutect2
- CHD2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV59120918; called by muse, mutect2
- CHRFAM7A | c.765G>C p.M255I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100241680; called by mutect2, varscan2
- CHRM2 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57775778; called by muse, mutect2, varscan2
- CHRM2 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV57775792; called by muse, mutect2, varscan2
- CHRM2 | c.1182G>T p.L394F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.58); catalogued as COSV57775799; called by muse, varscan2
- CHRM3 | c.170A>C p.D57A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV55093049; called by muse, mutect2, varscan2
- CHRNB4 | c.1457A>T p.H486L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.206); catalogued as COSV55716627; called by muse, mutect2, varscan2
- CITED2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100863127; called by muse, mutect2, varscan2
- CLCN4 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66467044; called by muse, mutect2, varscan2
- CLCN6 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 89/168 reads (53%) | catalogued as COSV56741097; called by muse, mutect2, varscan2
- CLCNKA | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV58892317; called by muse, varscan2
- CLDND1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV57859118; called by muse, mutect2, varscan2
- CLEC5A | c.444del p.F148Lfs*19 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as COSV69397984; called by mutect2, pindel, varscan2
- CNBD1 | c.249A>C p.K83N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.425); catalogued as COSV72917169, COSV72917327; called by muse, mutect2
- CNGA2 | c.1385T>A p.L462Q | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61705104; called by muse, mutect2, varscan2
- CNTN5 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200717963, COSV54296233, COSV99671964; called by muse, mutect2, varscan2
- CNTNAP2 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.082); catalogued as COSV62147968, COSV62177254; called by muse, mutect2, varscan2
- COL11A1 | c.4537G>T p.G1513C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62184768, COSV62187287; called by muse, mutect2, varscan2
- COL11A1 | c.3925-1G>A p.X1309_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100617964, COSV104421792, COSV62187293; called by muse, mutect2
- COL11A1 | c.3235C>G p.P1079A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV62187300; called by muse, mutect2, varscan2
- COL19A1 | c.1186C>A p.Q396K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.098); catalogued as COSV59575497, COSV59577048; called by muse, mutect2, varscan2
- COL1A2 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV99800847; called by muse, mutect2, varscan2
- COL1A2 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72658109, CM983821, CX973307, COSV51960411; called by muse, mutect2, varscan2
- COL24A1 | c.4081C>T p.Q1361* | Nonsense Mutation (SNP) | VAF 52/116 reads (45%) | catalogued as COSV65308377; called by muse, mutect2, varscan2
- COL3A1 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV58591016; called by muse, mutect2, varscan2
- COL4A6 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.85); PolyPhen benign (0.408); catalogued as COSV57869726; called by muse, mutect2, varscan2
- COL6A6 | c.1961T>G p.I654S | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62028707; called by muse, mutect2
- COL6A6 | c.3513C>G p.I1171M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.923); catalogued as rs755097067, COSV100650183, COSV62028722; called by muse, mutect2, varscan2
- CORO2A | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV59663591, COSV59664772; called by muse, mutect2, varscan2
- CPB2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.189); catalogued as COSV51675354; called by muse, mutect2, varscan2
- CPN2 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV60470784; called by muse, mutect2, varscan2
- CPNE1 | c.32C>G p.S11C (on ENST00000352393; = p.S16C on NM_003915.5) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV58292722; called by muse, mutect2
- CPNE5 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs1054285197, COSV55196924, COSV55197581; called by muse, mutect2, varscan2
- CPXCR1 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52162942; called by mutect2, varscan2
- CR1 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as rs200621891, COSV65462323; called by muse, mutect2, varscan2
- CRACD | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV51724430; called by muse, mutect2, varscan2
- CRIM1 | c.1644T>A p.C548* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54866671; called by muse, mutect2, varscan2
- CRISP3 | c.782T>C p.V261A (on ENST00000371159 / NM_001368123.1; = p.V243A on NM_006061.4) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53821224; called by muse, mutect2, varscan2
- CRMP1 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 115/228 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV61481170; called by muse, mutect2, varscan2
- CSF1R | c.2629C>A p.Q877K | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as CM1311989, COSV53837072; called by muse, mutect2, varscan2
- CSMD3 | c.6157C>T p.P2053S (on ENST00000297405 / NM_001363185.1; = p.P1949S on NM_052900.3) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV52219210, COSV99831986; called by muse, mutect2, varscan2
- CSMD3 | c.5210C>T p.S1737L (on ENST00000297405 / NM_001363185.1; = p.S1633L on NM_052900.3) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV52219255; called by muse, mutect2
- CSMD3 | c.3070C>A p.H1024N (on ENST00000297405 / NM_001363185.1; = p.H920N on NM_052900.3) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52219274, COSV99847264; called by muse, mutect2, varscan2
- CTTNBP2 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50413891; called by muse, mutect2, varscan2
- CUL4B | c.1138-2A>T p.X380_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60688682; called by muse, mutect2, varscan2
- CUZD1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV59028333; called by muse, mutect2, varscan2
- CXorf21 | c.772A>T p.R258* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100973353; called by muse, mutect2, varscan2
- CYLC2 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.119); catalogued as COSV66338097; called by muse, mutect2, varscan2
- CYP11B1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52828267; called by muse, mutect2, varscan2
- DAB1 | c.1043C>A p.P348H (on ENST00000371231; = p.P315H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs865869141, COSV64694083; called by muse, mutect2, varscan2
- DACT1 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100241568, COSV60021625; called by muse, mutect2, varscan2
- DACT1 | c.2396C>A p.P799Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV60021637; called by muse, mutect2, varscan2
- DAPK1 | c.1330-2A>T p.X444_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV63788733; called by muse, mutect2, varscan2
- DCAF12L2 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758493, COSV63582439, COSV63582926; called by muse, varscan2
- DCAF12L2 | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63580722, COSV63582449, COSV63583358; called by muse, varscan2
- DCAF8 | c.260A>T p.Y87F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58784562; called by muse, varscan2
- DCAF8L1 | c.1693A>T p.R565* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV71595360; called by muse, varscan2
- DCC | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); catalogued as COSV59111200; called by muse, mutect2, varscan2
- DCSTAMP | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52578474, COSV52579252; called by muse, mutect2, varscan2
- DENND5B | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV60904051; called by muse, mutect2, varscan2
- DGKH | c.2098G>C p.V700L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54934680; called by muse, mutect2, varscan2
- DGKI | c.2377C>G p.Q793E | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55947934, COSV55957104; called by muse, mutect2, varscan2
- DHX37 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs1445795833, COSV58135969; called by muse, mutect2, varscan2
- DICER1 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58622654; called by muse, mutect2, varscan2
- DLGAP1 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV59813715; called by mutect2, varscan2
- DMD | c.6402G>T p.E2134D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63766419; called by muse, mutect2, varscan2
- DMRTA1 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as COSV100364859; called by muse, mutect2, varscan2
- DNAAF1 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as COSV57577774; called by muse, mutect2, varscan2
- DNAH1 | c.10508G>T p.R3503L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV70226099, COSV70230894; called by muse, mutect2, varscan2
- DNAH2 | c.13259C>A p.A4420D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66721375; called by muse, mutect2, varscan2
- DNAH9 | c.7790C>A p.A2597E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52357039; called by muse, mutect2, varscan2
- DNAH9 | c.9012G>T p.E3004D | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV52357054; called by muse, mutect2, varscan2
- DNAH9 | c.12885T>A p.N4295K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.291); catalogued as COSV52357067; called by muse, mutect2
- DNAI2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56759722; called by muse, mutect2, varscan2
- DNAJC6 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54777091; called by muse, mutect2, varscan2
- DOCK11 | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52241653; called by muse, mutect2, varscan2
- DPH2 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.765); catalogued as COSV99356617; called by muse, mutect2
- DPM1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857752; called by muse, mutect2, varscan2
- DPYSL4 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV58308231; called by muse, mutect2, varscan2
- DRD2 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV60759413; called by muse, mutect2, varscan2
- DRD3 | c.759G>C p.K253N | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.301); catalogued as COSV55680894; called by muse, mutect2, varscan2
- DST | c.5966T>A p.L1989* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99759318; called by mutect2, varscan2
- DYNC1I1 | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100269142, COSV61463927; called by muse, varscan2
- EFCAB13 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV58949745; called by muse, mutect2, varscan2
- EGFL6 | c.1070T>A p.I357K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as COSV63634296; called by muse, mutect2, varscan2
- EGFL8 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100247075; called by muse, mutect2, varscan2
- EHBP1 | c.2553G>T p.R851S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV50424030; called by muse, mutect2, varscan2
- EIF5B | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56812286, COSV56814191; called by muse, mutect2, varscan2
- ELAVL2 | c.973A>T p.T325S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as COSV56364343; called by muse, mutect2, varscan2
- ELAVL4 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV100836841, COSV63917656; called by muse, mutect2, varscan2
- EMD | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs782193940, COSV100877416; called by muse, varscan2
- ENOX1 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV54904614, COSV54909270; called by muse, mutect2, varscan2
- EP400 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.036); catalogued as COSV57776376; called by muse, mutect2, varscan2
- EPB41L3 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59458099; called by muse, varscan2
- EPG5 | c.7111A>T p.S2371C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56351600; called by muse, mutect2, varscan2
- EPHA3 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60704625, COSV60711943; called by muse, mutect2, varscan2
- EPHA3 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV60711953; called by muse, mutect2, varscan2
- EPHA3 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.386); catalogued as rs755010537, COSV60711967; called by muse, mutect2, varscan2
- EPHA5 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300718125, COSV56652431; called by muse, varscan2
- EPHA7 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV65185522; called by muse, mutect2, varscan2
- EPHA7 | c.2398G>T p.V800L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV65185528; called by muse, mutect2, varscan2
- EPHB1 | c.2653C>G p.P885A | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs1307445052, COSV67663895; called by muse, mutect2
- ERBB4 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53546049; called by muse, mutect2, varscan2
- ERBB4 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53546067, COSV53566711; called by muse, mutect2, varscan2
- ERICH3 | c.3842T>C p.M1281T | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58610280; called by muse, mutect2, varscan2
- ERICH3 | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs765487001, COSV58610294, COSV58611622; called by muse, mutect2, varscan2
- ERVW-1 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV101423865; called by muse, mutect2, varscan2
- ESRRB | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1329201495, COSV55063120; called by muse, mutect2, varscan2
- ETNPPL | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV56596352; called by muse, mutect2, varscan2
- ETV3L | c.407C>A p.A136E | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV71901012, COSV71901134; called by muse, mutect2, varscan2
- EVC | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV53834109; called by muse, mutect2, varscan2
- EVC2 | c.1068G>C p.E356D | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV60396032; called by muse, mutect2, varscan2
- EYS | c.1460-1G>T p.X487_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60990107; called by muse, mutect2, varscan2
- FAM120B | c.2400G>T p.M800I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53005436; called by muse, mutect2, varscan2
- FAM184A | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58855666; called by muse, mutect2, varscan2
- FAM186B | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.762); catalogued as COSV57722017; called by muse, mutect2, varscan2
- FAM237A | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69305135; called by muse, mutect2, varscan2
- FAM3C | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63434778, COSV63435821; called by muse, mutect2, varscan2
- FAM47C | c.889del p.E297Sfs*528 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | catalogued as COSV100792408; called by mutect2, pindel, varscan2
- FAM9A | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV66813441; called by muse, varscan2
- FAN1 | c.1532C>A p.T511N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV62951082; called by muse, mutect2, varscan2
- FANCB | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.226); catalogued as COSV60760506; called by muse, mutect2, varscan2
- FANCI | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55529219; called by muse, mutect2, varscan2
- FAT3 | c.2566A>G p.R856G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.399); catalogued as COSV53130207; called by muse, mutect2, varscan2
- FAT3 | c.7288G>T p.E2430* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV53130236; called by muse, mutect2, varscan2
- FBLN2 | c.2302T>A p.C768S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV55486535; called by muse, mutect2
- FBN1 | c.3971A>T p.N1324I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV57320823; called by muse, mutect2, varscan2
- FBP2 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64694887; called by muse, mutect2, varscan2
- FBXL20 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 35/74 reads (47%) | catalogued as COSV52900448; called by muse, mutect2, varscan2
- FCRL2 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63834028; called by muse, mutect2, varscan2
- FGD5 | c.2781T>A p.D927E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53245730; called by muse, mutect2, varscan2
- FGFR2 | c.2032A>G p.R678G | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as CM020145, COSV60639272; called by muse, mutect2, varscan2
- FIGNL1 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV63553689; called by muse, mutect2, varscan2
- FMN2 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV60420273, COSV60436202; called by muse, varscan2
- FMN2 | c.4888T>G p.S1630A | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV60436209; called by muse, mutect2, varscan2
- FN1 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118073; called by muse, mutect2, varscan2
- FN1 | c.1777G>T p.G593C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118076; called by muse, mutect2, varscan2
- FOXO1 | c.929G>T p.W310L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101092127; called by muse, mutect2, varscan2
- FOXP2 | c.1718G>A p.W573* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100646098, COSV63488315; called by muse, mutect2, varscan2
- FRG2 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.644); catalogued as COSV66459720; called by muse, mutect2, varscan2
- FRMPD1 | c.3293T>A p.I1098N | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as COSV66700886; called by muse, mutect2, varscan2
- FRRS1 | c.1613T>A p.M538K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54922892; called by muse, mutect2, varscan2
- FRZB | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV54554662; called by muse, mutect2, varscan2
- FUT9 | c.73T>A p.C25S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100134189; called by muse, mutect2, varscan2
- GABRA5 | c.847C>G p.R283G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59481451; called by muse, mutect2, varscan2
- GABRG3 | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61522126; called by muse, mutect2, varscan2
- GABRQ | c.1064G>T p.S355I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV64782584; called by muse, mutect2, varscan2
- GAK | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV58506234; called by muse, mutect2, varscan2
- GBP1 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 112/441 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV65083814; called by muse, mutect2, varscan2
- GCN1 | c.6187G>T p.D2063Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV56109853; called by muse, mutect2, varscan2
- GCN1 | c.4547G>T p.G1516V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56109863; called by muse, mutect2, varscan2
- GGT7 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as COSV60541300; called by muse, mutect2, varscan2
- GIMAP4 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.253); catalogued as COSV55433286; called by muse, mutect2, varscan2
- GLDC | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV58681506; called by muse, mutect2, varscan2
- GLI2 | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58042513; called by muse, mutect2, varscan2
- GLI3 | c.4168G>T p.G1390W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV67890301; called by muse, mutect2, varscan2
- GLRA2 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.672); catalogued as COSV54342720; called by muse, mutect2, varscan2
- GPC6 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV65516774; called by muse, varscan2
- GPD2 | c.534G>C p.K178N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60093795; called by muse, mutect2, varscan2
- GPR101 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs749244228, COSV99981594; called by muse, mutect2, varscan2
- GPR141 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57732790; called by muse, mutect2, varscan2
- GPR148 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV59308415; called by muse, mutect2, varscan2
- GPR149 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67668010; called by muse, mutect2, varscan2
- GPR171 | c.337T>A p.C113S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56383968; called by muse, mutect2, varscan2
- GRID2 | c.1456T>A p.Y486N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56222319; called by muse, mutect2, varscan2
- GRIN2B | c.4179C>G p.D1393E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV74206066, COSV74206481, COSV74206503; called by muse, mutect2, varscan2
- GRM3 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV64474153; called by muse, mutect2, varscan2
- GRM7 | c.527A>T p.Q176L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100738146, COSV63149534; called by muse, mutect2, varscan2
- GSTZ1 | c.475-2A>T p.X159_splice | Splice Site (SNP) | VAF 38/146 reads (26%) | catalogued as COSV99374578; called by muse, mutect2
- GUF1 | c.1526G>C p.R509T | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1053912444, COSV55783283; called by muse, mutect2, varscan2
- GXYLT1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99788989; called by muse, mutect2, varscan2
- GXYLT1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1204486576, COSV99788998; called by muse, mutect2, varscan2
- HBB | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.844); catalogued as CD045243, CM142147, COSV58942580; called by muse, mutect2, varscan2
- HBG2 | c.341T>A p.V114D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100400688; called by muse, mutect2, varscan2
- HCN1 | c.1696G>T p.V566L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV57509776, COSV57518414, COSV57531864; called by muse, mutect2, varscan2
- HCRTR2 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63796665; called by muse, mutect2, varscan2
- HDAC4 | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV61868375; called by muse, mutect2, varscan2
- HECTD4 | c.7559G>T p.R2520L | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as rs1206631780, COSV66394152; called by muse, mutect2, varscan2
- HECW2 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV53663648; called by muse, mutect2, varscan2
- HGF | c.1093T>A p.C365S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55951738; called by muse, mutect2, varscan2
- HLTF | c.1640A>T p.H547L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV59501719; called by muse, mutect2, varscan2
- HOOK3 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV56883911; called by muse, mutect2, varscan2
- HRNR | c.2065G>T p.G689C | Missense Mutation (SNP) | VAF 215/418 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV64259516; called by muse, mutect2, varscan2
- HSF5 | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60417601; called by muse, mutect2, varscan2
- HSPA13 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53465090; called by muse, mutect2, varscan2
- HTR1D | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as rs1341341750, COSV100025040; called by muse, mutect2, varscan2
- HTT | c.4006A>T p.S1336C | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61864364; called by muse, mutect2, varscan2
- IFI44L | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV60728157; called by muse, mutect2, varscan2
- IFNA5 | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV99423751; called by muse, mutect2, varscan2
- IFT140 | c.3271-2A>T p.X1091_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54153491; called by muse, mutect2, varscan2
- IFT81 | c.1434G>C p.M478I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1226564527, COSV54363804; called by muse, mutect2, varscan2
- IGFN1 | c.3535G>T p.A1179S (on ENST00000295591 / NM_001367841.1; = p.A3636S on NM_001164586.2) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55175586; called by muse, mutect2, varscan2
- IKBKE | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65625934; called by muse, mutect2, varscan2
- IL1RL1 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52117711, COSV52119105; called by muse, mutect2, varscan2
- IL2 | c.147T>A p.N49K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV56986304; called by muse, mutect2, varscan2
- IL6R | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV59817280; called by muse, mutect2, varscan2
- IMMP2L | c.408G>T p.P136= | Splice Region (SNP) | VAF 10/88 reads (11%) | catalogued as COSV59246627; called by muse, mutect2, varscan2
- INPP1 | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59416344; called by muse, mutect2
- INPPL1 | c.2620G>A p.V874M | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1250873653, COSV53356667; called by muse, mutect2, varscan2
- INSRR | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.34); catalogued as rs1004080370, COSV63873485, COSV63874770, COSV63876170; called by muse, mutect2
- IPO7 | c.3076A>T p.S1026C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV65685726; called by muse, mutect2, varscan2
- IQCG | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54563240; called by muse, mutect2, varscan2
- IQCG | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs1560113286, COSV54563251; called by muse, mutect2, varscan2
- IQCH | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV60055001; called by muse, mutect2, varscan2
- IQCJ | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.107); catalogued as COSV101188767, COSV67337569; called by muse, mutect2, varscan2
- IQGAP2 | c.2452A>G p.N818D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs982433336, COSV57175955; called by muse, mutect2, varscan2
- IRF6 | c.509-1G>T p.X170_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV65419596; called by muse, mutect2, varscan2
- ITGAX | c.561+1G>T p.X187_splice | Splice Site (SNP) | VAF 15/80 reads (19%) | catalogued as COSV51647302; called by muse, mutect2, varscan2
- ITIH4 | c.90+1G>C p.X30_splice | Splice Site (SNP) | VAF 29/174 reads (17%) | catalogued as COSV99819798; called by muse, mutect2
- ITPRID1 | c.1827C>A p.F609L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV60076685; called by muse, mutect2, varscan2
- ITSN1 | c.3662G>T p.W1221L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV67157257; called by muse, mutect2, varscan2
- JPH4 | c.1413G>A p.W471* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV58113500; called by muse, mutect2, varscan2
- KCNA4 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60250901, COSV60253545; called by muse, varscan2
- KCNA4 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60253557; called by muse, varscan2
- KCNB2 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV73049937, COSV73050498; called by muse, mutect2, varscan2
- KCNH5 | c.2789C>A p.A930D | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.042); catalogued as rs562140660, COSV59764404; called by muse, mutect2, varscan2
- KCNJ16 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52250916, COSV52255305; called by muse, mutect2, varscan2
- KCNK10 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV100068850, COSV56647252; called by muse, varscan2
- KCNT2 | c.2849del p.S950Lfs*28 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as COSV99652049; called by mutect2, pindel, varscan2
- KCNV1 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV52086905; called by muse, mutect2, varscan2
- KDM7A | c.2663C>A p.S888* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as COSV50092775; called by muse, mutect2, varscan2
- KIAA0586 | c.3489G>A p.M1163I (on ENST00000619416 / NM_001244190.2; = p.M1102I on NM_014749.5) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs757075046, COSV99708753; called by muse, mutect2, varscan2
- KIAA1109 | c.12517G>T p.A4173S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52679294; called by muse, mutect2, varscan2
- KIAA1755 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54077762; called by muse, mutect2, varscan2
- KIF13A | c.5333A>C p.H1778P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52455590; called by muse, mutect2, varscan2
- KIF16B | c.3143G>T p.G1048V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV61708138; called by muse, mutect2
- KIF1A | c.5075G>T p.R1692M (on ENST00000320389 / NM_001379639.1; = p.R1684M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV57493158; called by muse, mutect2, varscan2
- KIF3B | c.2227G>T p.G743W | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65228082; called by muse, mutect2, varscan2
- KIR2DL3 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 187/479 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs575849272, COSV60898433; called by muse, mutect2, varscan2
- KLF8 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs1047950271, COSV63847830; called by muse, mutect2, varscan2
- KLHL13 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.561); catalogued as COSV53249410; called by muse, mutect2, varscan2
- KLHL34 | c.590T>G p.L197R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101069984; called by muse, mutect2
- KMT2B | c.6238G>T p.G2080C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV55863523; called by muse, mutect2, varscan2
- KMT2C | c.9264T>G p.D3088E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV51455626; called by muse, mutect2
- KMT2D | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV56416388; called by muse, mutect2
- KRT10 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs752448327, COSV99510268; called by muse, mutect2
- KRTAP13-3 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV61878894; called by muse, mutect2, varscan2
- KRTAP21-1 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100624956; called by muse, mutect2, varscan2
- L1CAM | c.1315G>C p.V439L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100648961, COSV62828679; called by muse, mutect2, varscan2
- LAMB1 | c.2386C>G p.P796A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV55966522; called by muse, varscan2
- LDB2 | c.132G>A p.E44= | Splice Region (SNP) | VAF 38/89 reads (43%) | catalogued as COSV58772544; called by muse, mutect2, varscan2
- LDHC | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55004716; called by muse, mutect2, varscan2
- LDLRAD3 | c.102C>G p.N34K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV59683989; called by muse, mutect2, varscan2
- LHFPL4 | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV99805665; called by muse, mutect2, varscan2
- LILRA2 | c.806G>T p.W269L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV52193082; called by muse, mutect2, varscan2
- LIPC | c.1251G>C p.K417N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV54423624; called by muse, mutect2, varscan2
- LMBRD2 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56950891; called by muse, mutect2, varscan2
- LONRF3 | c.1812G>T p.G604= (on ENST00000371628 / NM_001031855.3; = p.G563= on NM_024778.5) | Splice Region (SNP) | VAF 39/248 reads (16%) | catalogued as COSV59153938; called by muse, mutect2, varscan2
- LPCAT1 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV52038997; called by muse, mutect2, varscan2
- LRFN5 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV53256598; called by muse, mutect2, varscan2
- LRP12 | c.1982G>T p.R661I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV52630284; called by muse, mutect2, varscan2
- LRP1B | c.11084G>T p.G3695V | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV104431954, COSV67238013; called by muse, mutect2, varscan2
- LRP2 | c.3308C>A p.T1103N | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as COSV55559399; called by muse, mutect2, varscan2
- LRR1 | c.953A>G p.Q318R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV100023264; called by muse, mutect2, varscan2
- LRRC7 | c.3083G>T p.G1028V (on ENST00000651989 / NM_001370785.2; = p.G995V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV50490244; called by muse, mutect2, varscan2
- LRRIQ3 | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV63041768, COSV63042221; called by muse, mutect2, varscan2
- LRRIQ3 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV63045640; called by muse, mutect2, varscan2
- LRRN3 | c.1730T>A p.V577E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57821140; called by mutect2, varscan2
- LTBP1 | c.2468C>A p.P823H (on ENST00000404816 / NM_206943.4; = p.P497H on NM_000627.4) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63190493; called by muse, mutect2, varscan2
- LYPLAL1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV65106853; called by muse, mutect2, varscan2
- LYST | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV67706220, COSV67708680; called by muse, mutect2, varscan2
- MAGEC1 | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 83/480 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV53575446; called by muse, mutect2, varscan2
- MAGEC2 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV56000053; called by muse, mutect2, varscan2
- MAGI1 | c.3467G>T p.G1156V (on ENST00000402939 / NM_001033057.2; = p.G1185V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 226/606 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58313051; called by muse, mutect2, varscan2
- MAGI1 | c.1434C>G p.S478R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58332498; called by muse, mutect2, varscan2
- MAP1B | c.6029C>A p.T2010N | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV57101173; called by muse, mutect2, varscan2
- MAP3K19 | c.2530C>T p.H844Y | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100209129; called by muse, mutect2, varscan2
- MAP4K3 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781301191, COSV55714570; called by muse, mutect2, varscan2
- MASP1 | c.2003G>T p.W668L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61824127; called by muse, mutect2, varscan2
- MAX | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52417802; called by muse, mutect2, varscan2
- MCEE | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99731268; called by muse, mutect2, varscan2
- MCM2 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54034647, COSV99412888; called by muse, mutect2, varscan2
- MCM6 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750353136, COSV51467277; called by muse, mutect2, varscan2
- MED1 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV56126074; called by muse, mutect2, varscan2
- MED12L | c.2803C>A p.L935I | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV56383976; called by muse, mutect2, varscan2
- MEF2A | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV57534909; called by muse, mutect2, varscan2
- MEGF10 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57251620; called by muse, mutect2, varscan2
- MEGF10 | c.1871G>C p.C624S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57251630; called by muse, mutect2, varscan2
- MFAP4 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55190882; called by muse, mutect2, varscan2
- MGAT5B | c.1906G>T p.A636S (on ENST00000569840 / NM_001199172.2; = p.A634S on NM_144677.3) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56931218; called by muse, mutect2
- MIA2 | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54495118; called by muse, mutect2, varscan2
- MID1 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58195998; called by muse, mutect2, varscan2
- MLIP | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV51431966; called by muse, mutect2, varscan2
- MMP16 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54171969; called by muse, mutect2, varscan2
- MOGAT1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV101485125, COSV71479894; called by muse, mutect2, varscan2
- MOSPD2 | c.993-1G>T p.X331_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV66860324; called by muse, mutect2, varscan2
- MPP1 | c.1355A>C p.Q452P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs781886731, COSV65729779; called by muse, mutect2, varscan2
- MSANTD3 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV58494666; called by muse, mutect2
- MSH2 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436608214, CD982805, COSV51880860; called by muse, mutect2, varscan2
- MTARC2 | c.514T>A p.L172M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63765855; called by muse, mutect2, varscan2
- MTMR14 | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56005708; called by muse, mutect2, varscan2
- MUC16 | c.34426C>A p.P11476T | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV67475439; called by muse, mutect2, varscan2
- MUC16 | c.18773C>A p.T6258K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV67475446; called by muse, mutect2, varscan2
- MUC17 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 44/338 reads (13%) | catalogued as COSV60292786, COSV60301037; called by muse, mutect2, varscan2
- MUC17 | c.11305C>A p.P3769T | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.573); catalogued as COSV60292803; called by muse, mutect2, varscan2
- MUC3A | c.8154T>A p.S2718R | Missense Mutation (SNP) | VAF 123/1142 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV60218199; called by muse, mutect2, varscan2
- MX2 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV58097237; called by muse, mutect2, varscan2
- MXRA5 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 107/171 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54234986, COSV54239582; called by muse, mutect2, varscan2
- MYBL2 | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53831128; called by muse, mutect2
- MYH1 | c.4917G>T p.M1639I | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56851173; called by muse, mutect2, varscan2
- MYH4 | c.2482G>T p.V828L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV55120645; called by muse, mutect2
- MYH7 | c.4243G>C p.E1415Q | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1183549974, COSV62516678, COSV62520715; called by muse, mutect2, varscan2
- MYPN | c.2563A>T p.M855L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62735155; called by muse, mutect2
- N4BP2 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV54703568; called by muse, varscan2
- NALCN | c.4951G>A p.G1651R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV51922367; called by muse, mutect2, varscan2
- NAP1L2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.222); catalogued as COSV65172659; called by muse, mutect2, varscan2
- NAT1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100306566; called by muse, mutect2, varscan2
- NDUFA10 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV53153655; called by muse, mutect2
- NDUFS2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV57155237; called by muse, mutect2, varscan2
- NEBL | c.2869-1G>A p.X957_splice | Splice Site (SNP) | VAF 8/136 reads (6%) | catalogued as COSV101009328; called by muse, mutect2
- NEGR1 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV60852524; called by muse, mutect2, varscan2
- NEIL3 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52810491, COSV52811457; called by muse, mutect2, varscan2
- NEXMIF | c.2273A>C p.N758T | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV50042741; called by muse, mutect2
- NHS | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs765028709, COSV101197104, COSV66277399; called by muse, mutect2, varscan2
- NID2 | c.2006T>A p.L669Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53498299; called by muse, mutect2, varscan2
- NID2 | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as COSV53498307; called by muse, mutect2, varscan2
- NLGN1 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64327158, COSV64345683; called by muse, mutect2
- NOA1 | c.1425C>G p.H475Q | Missense Mutation (SNP) | VAF 132/236 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV51737671; called by muse, mutect2, varscan2
- NPAS3 | c.1624G>A p.A542T (on ENST00000356141 / NM_001164749.2; = p.A510T on NM_022123.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV60841909; called by muse, mutect2, varscan2
- NR0B1 | c.1273A>T p.R425* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as CM980039, COSV66764239; called by muse, mutect2, varscan2
- NRG3 | c.1850C>A p.S617Y (on ENST00000404547 / NM_001370084.1; = p.S593Y on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV64547547, COSV64569139; called by muse, mutect2, varscan2
- NRK | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54599484, COSV54605134; called by muse, mutect2, varscan2
- NRXN3 | c.1493G>A p.R498Q (on ENST00000335750 / NM_001330195.2; = p.R125Q on NM_004796.6) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.653); catalogued as rs1399068257, COSV59758041; called by muse, mutect2, varscan2
- NRXN3 | c.2986G>T p.G996C (on ENST00000335750 / NM_001330195.2; = p.G623C on NM_004796.6) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59765071; called by muse, mutect2, varscan2
- NSMCE2 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54899821; called by muse, mutect2, varscan2
- NTAQ1 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54875044; called by muse, mutect2, varscan2
- NTM | c.80C>A p.T27K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV66183586; called by muse, mutect2, varscan2
- NTM | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs200656449, COSV66203709, COSV66207515; called by muse, mutect2, varscan2
- NTNG1 | c.889T>A p.C297S | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53976421; called by muse, mutect2, varscan2
- NTNG2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV62367394; called by muse, mutect2, varscan2
- NUDT5 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750033387, COSV66718621; called by muse, mutect2, varscan2
- NXF1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV53674655; called by muse, mutect2, varscan2
- NXF3 | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV67704164; called by muse, mutect2, varscan2
- OCA2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1212574604, COSV62349210; called by muse, mutect2, varscan2
- OCRL | c.2342-2A>T p.X781_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as COSV63981160; called by muse, mutect2, varscan2
- OGT | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV101035589; called by muse, mutect2, varscan2
- OLFM3 | c.1066C>A p.L356M (on ENST00000338858 / NM_001288821.1; = p.L336M on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV58800271; called by muse, mutect2, varscan2
- OLFML2A | c.714T>G p.S238R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV56584126; called by muse, mutect2, varscan2
- OMA1 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV62255844; called by muse, mutect2, varscan2
- OPRL1 | c.307A>T p.T103S | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV61092012; called by muse, mutect2, varscan2
- OR10A2 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs758387748, COSV100225166; called by muse, mutect2, varscan2
- OR10G4 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.614); catalogued as COSV100304667, COSV100304953; called by muse, mutect2, varscan2
- OR10G9 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66686404; called by muse, mutect2, varscan2
- OR10J5 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs973924555, COSV100604817; called by muse, mutect2, varscan2
- OR10K1 | c.778T>A p.L260I | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56872611; called by muse, mutect2
- OR10R2 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV63769010; called by muse, mutect2, varscan2
- OR10Z1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63525355; called by muse, mutect2, varscan2
- OR13C5 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV66164795; called by muse, mutect2, varscan2
- OR13G1 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62944456; called by muse, mutect2, varscan2
- OR13G1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV62944523; called by muse, mutect2, varscan2
- OR1C1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV68715895; called by muse, mutect2, varscan2
- OR2L3 | c.659T>G p.V220G | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63455506; called by muse, varscan2
- OR2L8 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV61727204; called by muse, mutect2, varscan2
- OR2M3 | c.337T>A p.F113I | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV71759108; called by muse, mutect2, varscan2
- OR2T33 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58815956; called by muse, mutect2, varscan2
- OR2T34 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60900848; called by muse, mutect2, varscan2
- OR4A15 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59035995; called by muse, mutect2, varscan2
- OR4C6 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as rs762109098, COSV58604748; called by muse, mutect2, varscan2
- OR4K13 | c.436T>G p.L146V | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59859917; called by muse, mutect2
- OR4M1 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV100271483; called by muse, mutect2, varscan2
- OR51F2 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1267958102, COSV59065170; called by muse, mutect2, varscan2
- OR5AC2 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 114/299 reads (38%) | catalogued as COSV100684401; called by muse, mutect2, varscan2
- OR5B12 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56904391; called by muse, mutect2, varscan2
- OR5D16 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371077894, COSV65722268; called by muse, mutect2, varscan2
- OR5F1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190524347, COSV53546231; called by muse, mutect2, varscan2
- OR5L2 | c.614T>G p.L205W | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV65724415; called by muse, varscan2
- OR6A2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60264407, COSV60265207; called by muse, mutect2, varscan2
- OR6C74 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as rs755511988, COSV59606692; called by muse, mutect2, varscan2
- OR6N1 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58649143; called by muse, mutect2, varscan2
- OR7D4 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV58071618; called by muse, mutect2, varscan2
- OR8D4 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58430757, COSV58430785; called by muse, mutect2, varscan2
- OR8H2 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV57945559; called by muse, varscan2
- OR8I2 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56168599; called by muse, varscan2
- OR8I2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV56168609, COSV56170676; called by muse, varscan2
- OTC | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV50002553; called by muse, mutect2, varscan2
- OTC | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as CM983941, COSV50002563; called by muse, mutect2, varscan2
- OTOF | c.4921C>A p.R1641S (on ENST00000272371 / NM_194248.3; = p.R874S on NM_004802.4) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV55507037; called by muse, mutect2, varscan2
- OTOF | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs773331735, COSV55507073; called by muse, mutect2, varscan2
- OTOL1 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV60007197; called by muse, mutect2, varscan2
- OTOL1 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as COSV60007203, COSV60008924; called by muse, mutect2, varscan2
- P4HTM | c.1426C>A p.R476S (on ENST00000383729 / NM_177939.3; = p.R537S on NM_177938.2) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as COSV59087856; called by muse, mutect2, varscan2
- PABPC3 | c.1885C>A p.P629T | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99879972; called by muse, mutect2, varscan2
- PAG1 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55058105, COSV55058886; called by muse, mutect2
- PAK5 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62030375; called by muse, mutect2, varscan2
- PAPPA | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs778522678, COSV60285941, COSV60285959; called by muse, varscan2
- PAPPA | c.2503T>A p.C835S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60286230; called by muse, mutect2, varscan2
- PAPPA2 | c.3101C>A p.A1034E | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV62801216; called by muse, mutect2, varscan2
- PARD3B | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62516617; called by muse, mutect2
- PARP11 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV57395710; called by muse, mutect2, varscan2
- PBXIP1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV63777359; called by muse, mutect2
- PCDH10 | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52097047; called by muse, mutect2, varscan2
- PCDH10 | c.2660A>T p.Y887F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV52097058; called by muse, mutect2, varscan2
- PCDH11X | c.1397T>A p.F466Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53477287; called by muse, mutect2, varscan2
- PCDHA1 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | catalogued as COSV65375039; called by muse, mutect2, varscan2
- PCDHA11 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.41); catalogued as COSV56516175; called by muse, mutect2, varscan2
- PCDHA3 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554122119, COSV63542970; called by muse, mutect2, varscan2
- PCDHB2 | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99523517; called by muse, mutect2, varscan2
- PCDHGB1 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53940701, COSV53972084; called by muse, mutect2, varscan2
- PCDHGB3 | c.375T>A p.D125E | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53972099; called by muse, mutect2, varscan2
- PCK2 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV99394643; called by muse, mutect2
- PCLO | c.5812G>T p.D1938Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV61643859; called by muse, mutect2
- PCSK6 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV59342050; called by muse, mutect2
- PDE3B | c.2722A>T p.K908* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56385753; called by muse, mutect2, varscan2
- PDIA5 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV60250048; called by muse, mutect2, varscan2
- PDILT | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs768109168, COSV56702699; called by muse, mutect2, varscan2
- PEG10 | c.508A>T p.K170* (on ENST00000482108 / NM_001040152.2; = p.K204* on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/184 reads (12%) | catalogued as COSV101509949; called by muse, mutect2, varscan2
- PELI2 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV50712149; called by muse, mutect2, varscan2
- PGLYRP2 | c.1682C>A p.S561Y | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.295); catalogued as COSV99484266; called by mutect2, varscan2
- PHKA2 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV66054690; called by muse, mutect2, varscan2
- PHPT1 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56033394; called by muse, mutect2, varscan2
- PHRF1 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1259558217, COSV52757611; called by muse, mutect2
- PI15 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV52642439; called by muse, mutect2, varscan2
- PIGR | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV62904370; called by muse, mutect2, varscan2
- PIK3C2G | c.4040C>A p.S1347Y (on ENST00000676171; = p.S1306Y on NM_004570.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV56802318, COSV56814730; called by muse, mutect2, varscan2
- PKD1L2 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs772540799, COSV55164044; called by muse, mutect2, varscan2
- PKD2L1 | c.1723A>T p.K575* | Nonsense Mutation (SNP) | VAF 39/62 reads (63%) | catalogued as COSV58396727; called by muse, mutect2, varscan2
- PKIA | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100775179; called by muse, mutect2, varscan2
- PLB1 | c.1027A>T p.S343C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV59828690; called by muse, mutect2, varscan2
- PLCB4 | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV53806095; called by muse, mutect2, varscan2
- PLD2 | c.2673G>T p.L891F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV54007021; called by muse, mutect2, varscan2
- PLEKHG4B | c.1537G>T p.G513* (on ENST00000283426; = p.G869* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV52049615; called by muse, mutect2, varscan2
- PLIN5 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113658; called by muse, mutect2, varscan2
- PLXNA3 | c.2401C>A p.P801T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as COSV63754512; called by muse, varscan2
- POLE | c.5024G>A p.R1675H | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1011938171, COSV57683459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMC | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99256965; called by muse, mutect2, varscan2
- PPFIA3 | c.3255G>C p.L1085F | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53257124, COSV53257926; called by muse, mutect2, varscan2
- PPP1R26 | c.1825A>G p.K609E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV63356042; called by muse, mutect2, varscan2
- PPP1R42 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100221439; called by muse, mutect2
- PPP2CB | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55328894; called by muse, mutect2, varscan2
- PPP2R1B | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV59536144; called by muse, mutect2, varscan2
- PRAMEF2 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1063787, COSV53576618; called by muse, mutect2, varscan2
- PRDX1 | c.251A>C p.H84P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53114013; called by muse, mutect2, varscan2
- PRG4 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63355849; called by muse, varscan2
- PROS1 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.476); catalogued as COSV101260775; called by muse, mutect2, varscan2
- PROS1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs370129669, COSV67774805; called by muse, mutect2, varscan2
- PROSER1 | c.1558G>C p.A520P | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV61488248, COSV61489732; called by muse, varscan2
- PROSER1 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV61488255; called by muse, varscan2
- PRPF4B | c.1405C>G p.R469G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV61784549; called by mutect2, varscan2
- PRR30 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV53206764; called by muse, mutect2, varscan2
- PRUNE2 | c.7066G>T p.V2356L | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV65043141; called by muse, mutect2, varscan2
- PRUNE2 | c.3922G>T p.G1308W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV65043144; called by muse, mutect2, varscan2
- PRUNE2 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.486); catalogued as COSV100945105, COSV65043150; called by muse, mutect2, varscan2
- PSEN2 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60916941; called by muse, mutect2, varscan2
- PSG11 | c.281C>G p.A94G | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60453549, COSV60456051; called by muse, mutect2, varscan2
- PSKH2 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52611088; called by muse, mutect2, varscan2
- PSME4 | c.3477G>T p.L1159= | Splice Region (SNP) | VAF 53/135 reads (39%) | catalogued as COSV66365899; called by muse, mutect2, varscan2
- PTGER2 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV99817708; called by muse, mutect2, varscan2
- PTP4A1 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65715312; called by muse, mutect2, varscan2
- PTPRD | c.4729A>G p.K1577E | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV61957320, COSV61979263; called by muse, mutect2
- PTPRD | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61957335, COSV61971137; called by muse, mutect2, varscan2
- PTPRD | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61957357; called by muse, mutect2, varscan2
- PTPRD | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV104419388, COSV61957376; called by muse, mutect2, varscan2
- PTPRN | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV55349369; called by muse, mutect2, varscan2
- PTPRN2 | c.2805G>T p.R935S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101153363; called by muse, mutect2, varscan2
- PTPRN2 | c.2804G>T p.R935M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1169541311, COSV101153374; called by muse, mutect2, varscan2
- PTTG1 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV61677849, COSV61678098; called by muse, mutect2, varscan2
- PXK | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as rs371239729, COSV104406741, COSV57090325; called by muse, mutect2, varscan2
- R3HDML | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53835506; called by muse, mutect2, varscan2
- RAD50 | c.2116C>G p.R706G | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV54749843, COSV99529486; called by muse, mutect2, varscan2
- RAI2 | c.1257C>A p.S419R | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100518506; called by muse, mutect2
- RALGPS2 | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62678795; called by muse, mutect2, varscan2
- RAPGEF5 | c.960G>C p.L320F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59785969; called by muse, mutect2, varscan2
- RASSF6 | c.565G>C p.A189P (on ENST00000342081 / NM_201431.2; = p.A157P on NM_177532.5) | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56719122; called by muse, mutect2, varscan2
- RBM41 | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV52564050; called by muse, mutect2, varscan2
- RC3H2 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV59013198; called by muse, mutect2, varscan2
- RECQL4 | c.2941G>C p.G981R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as COSV56741579; called by muse, mutect2, varscan2
- REG1B | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 57/170 reads (34%) | catalogued as COSV59304742, COSV59306343; called by muse, mutect2, varscan2
- RHBDD2 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV50087405; called by muse, mutect2, varscan2
- RHCG | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs149510924, COSV51516671; called by muse, mutect2, varscan2
- RHOT1 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61716620; called by muse, mutect2, varscan2
- RIPPLY2 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV100860763; called by mutect2, varscan2
- RIT2 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV58668804; called by muse, mutect2, varscan2
- RLIM | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60327363; called by muse, mutect2, varscan2
- RNASEH1 | c.804A>G p.I268M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs993175463, COSV59439014; called by muse, mutect2, varscan2
- RND3 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV99812155; called by muse, mutect2, varscan2
- RNF123 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as COSV59688754; called by muse, mutect2
- RNF144A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV57983305; called by muse, mutect2, varscan2
- RNF213 | c.10501G>C p.E3501Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV60401084; called by muse, mutect2
- RORA | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100174279; called by muse, mutect2, varscan2
- RORA | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV100174282; called by muse, mutect2, varscan2
- RP1L1 | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs747729751, COSV66751754, COSV66756654, COSV66760347; called by muse, mutect2, varscan2
- RPS11 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV54526684; called by muse, mutect2, varscan2
- RPS6KA2 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs754636268, COSV55822961; called by muse, mutect2, varscan2
- RPUSD4 | c.1085A>G p.N362S | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53599510; called by muse, mutect2, varscan2
- RRAGB | c.678G>T p.W226C (on ENST00000262850 / NM_016656.4; = p.W198C on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53330339, COSV99469329; called by muse, mutect2, varscan2
- RSPO1 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV62974352, COSV62974548; called by muse, mutect2, varscan2
- RTP2 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV64079170; called by muse, mutect2, varscan2
- RUFY3 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56914783; called by muse, mutect2, varscan2
- RYR1 | c.424+1G>C p.X142_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV62101265; called by muse, mutect2, varscan2
- RYR2 | c.12733C>A p.L4245M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.804); catalogued as COSV63692939; called by muse, mutect2, varscan2
- RYR2 | c.12920G>T p.R4307L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV63684322, COSV63691311; called by muse, mutect2, varscan2
- RYR3 | c.6715G>T p.G2239W | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109457, COSV63109700; called by muse, mutect2, varscan2
- SAMD9L | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV59082682; called by muse, mutect2, varscan2
- SBF1 | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV62368392; called by muse, mutect2, varscan2
- SCFD1 | c.141T>G p.I47M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61724790; called by muse, mutect2, varscan2
- SCN3A | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV51814183; called by muse, mutect2, varscan2
- SDHB | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV64965391; called by muse, mutect2, varscan2
- SENP6 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV59192023; called by muse, mutect2
- SERPINA4 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54070503; called by muse, mutect2, varscan2
- SERPINA5 | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 111/378 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV61574380; called by muse, varscan2
- SERPINA6 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV58585777; called by muse, mutect2, varscan2
- SERPINB10 | c.1057G>C p.A353P | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53073787; called by muse, mutect2
- SETBP1 | c.3923C>A p.T1308K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV56323528, COSV56326778; called by muse, mutect2, varscan2
- SETD2 | c.3653A>C p.Q1218P | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV57441449; called by muse, mutect2, varscan2
- SFMBT1 | c.1964G>A p.S655N | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.189); catalogued as COSV56254908; called by muse, mutect2, varscan2
- SFXN5 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55587763; called by muse, mutect2, varscan2
- SH2B1 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59464160; called by muse, mutect2, varscan2
- SH2D4B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV57897251; called by muse, mutect2, varscan2
- SHC3 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65439142; called by muse, mutect2
- SHTN1 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV53383996; called by muse, mutect2, varscan2
- SI | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52285126; called by muse, mutect2, varscan2
- SI | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52285143; called by muse, mutect2, varscan2
- SIGLEC10 | c.1580A>T p.H527L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as rs374739550; called by muse, mutect2, varscan2
- SIGLEC7 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58315912, COSV58316471; called by muse, mutect2, varscan2
- SIRPB1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.697); catalogued as COSV53539346; called by muse, mutect2, varscan2
- SKIDA1 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV71610962; called by muse, mutect2, varscan2
- SKP1 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); catalogued as COSV100104624; called by muse, mutect2, varscan2
- SLC10A2 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55359953; called by muse, mutect2, varscan2
- SLC14A2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV54910466; called by muse, mutect2, varscan2
- SLC17A6 | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV54133379; called by muse, mutect2, varscan2
- SLC1A2 | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV53522687; called by muse, mutect2, varscan2
- SLC24A5 | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58317445, COSV58317996; called by muse, mutect2, varscan2
- SLC2A10 | c.1483T>A p.L495I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV63715100; called by muse, mutect2, varscan2
- SLC2A2 | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV58586612; called by muse, mutect2, varscan2
- SLC35F6 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60426703; called by muse, varscan2
- SLC35G3 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99269150; called by muse, mutect2, varscan2
- SLC38A2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56745448; called by muse, varscan2
- SLC3A1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV53223342; called by muse, mutect2, varscan2
- SLC52A1 | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as COSV54693142; called by muse, mutect2, varscan2
- SLC7A14 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51584544; called by muse, mutect2, varscan2
- SLITRK3 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.159); catalogued as COSV53849657; called by muse, mutect2, varscan2
- SLITRK3 | c.270G>C p.R90S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.966); catalogued as COSV53849670; called by muse, mutect2, varscan2
- SLITRK6 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101233285, COSV68390167; called by muse, mutect2, varscan2
- SMPD4 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60081125; called by muse, mutect2
- SORCS1 | c.2744C>A p.P915H | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53876846; called by muse, mutect2, varscan2
- SORCS1 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV53876859, COSV53904636; called by muse, mutect2, varscan2
- SORCS3 | c.3643del p.E1215Rfs*20 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as COSV100865636; called by mutect2, pindel, varscan2
- SOS1 | c.3390A>T p.P1130= | Splice Region (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101217244; called by muse, mutect2
- SOX30 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV53938090; called by muse, mutect2, varscan2
- SPAG5 | c.1679T>G p.L560R | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as COSV58802485; called by muse, mutect2, varscan2
- SPANXN2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 206/478 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV65127843, COSV65127901; called by muse, varscan2
- SPATA31D1 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV61197526; called by muse, mutect2, varscan2
- SPEF2 | c.2125A>G p.I709V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs983831915, COSV61549556; called by muse, mutect2, varscan2
- SPIC | c.561del p.K188Sfs*2 | Frame Shift Del (DEL) | VAF 56/143 reads (39%) | catalogued as COSV100162851; called by mutect2, pindel, varscan2
- SPP2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs764495552, COSV51445806; called by muse, mutect2, varscan2
- SPRR2E | c.35G>C p.C12S | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64203831, COSV64204017; called by muse, mutect2, varscan2
- SPTA1 | c.2098C>A p.Q700K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV63755456; called by muse, mutect2, varscan2
- SPTBN4 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV58952787; called by muse, mutect2, varscan2
- SRGAP3 | c.2127G>T p.M709I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV64535201; called by muse, mutect2, varscan2
- SRGAP3 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV64535212; called by muse, mutect2, varscan2
- SSC4D | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51882846; called by muse, mutect2, varscan2
- SSX7 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53340345; called by muse, mutect2, varscan2
- STARD3 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs200708532, COSV59223930; called by muse, mutect2, varscan2
- STAT5A | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV61807243; called by muse, mutect2, varscan2
- STC1 | c.441G>C p.E147D | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51688960, COSV99282748; called by muse, mutect2, varscan2
- STIM1 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV56156682, COSV56157305; called by muse, mutect2, varscan2
- STIMATE | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV100753840; called by muse, varscan2
- STK10 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51575478; called by muse, mutect2, varscan2
- STON2 | c.1760T>A p.L587Q (on ENST00000649389 / NM_001366849.2; = p.L530Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50843759, COSV50846860; called by muse, mutect2
- STPG4 | c.290_291insT p.Q98Afs*6 | Frame Shift Ins (INS) | VAF 39/197 reads (20%) | catalogued as COSV99681428; called by mutect2, pindel, varscan2
- SVIL | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345161192, COSV63444647; called by muse, mutect2, varscan2
- SVOP | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs749864029, COSV54466582; called by muse, mutect2, varscan2
- SYCP1 | c.2043+1G>A p.X681_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV65698701; called by muse, mutect2, varscan2
- SYNCRIP | c.1430A>T p.Y477F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); catalogued as COSV62288413; called by muse, mutect2, varscan2
- SYNE1 | c.585G>T p.Q195H (on ENST00000367255 / NM_182961.4; = p.Q202H on NM_033071.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV55017513, COSV55122322; called by muse, mutect2, varscan2
- SYNJ2 | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV62898323; called by muse, mutect2, varscan2
- SYT16 | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV70857460; called by muse, mutect2, varscan2
- SYTL4 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as COSV52168737; called by muse, mutect2, varscan2
- TACC2 | c.4934A>T p.E1645V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV57760157; called by muse, mutect2, varscan2
- TARS1 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99466408; called by muse, mutect2, varscan2
- TAS2R16 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs763580166, COSV50797488; called by muse, mutect2, varscan2
- TBC1D4 | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1317306828, COSV100884765; called by muse, mutect2
- TBCCD1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58662539; called by muse, mutect2, varscan2
- TBX15 | c.979C>A p.R327S (on ENST00000369429 / NM_001330677.2; = p.R221S on NM_152380.3) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs762139183, COSV52872690, COSV52875522; called by muse, mutect2, varscan2
- TBX21 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV51596773; called by muse, mutect2, varscan2
- TCAF2 | c.2488C>A p.L830M | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633629; called by muse, mutect2
- TCHHL1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs775384178, COSV64286269; called by mutect2, varscan2
- TECRL | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV67088066; called by muse, mutect2
- TENM1 | c.7777G>A p.G2593R | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64435116; called by muse, mutect2, varscan2
- TENM1 | c.5250C>A p.N1750K | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV64435121; called by muse, mutect2, varscan2
- TENM1 | c.2473C>A p.Q825K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV64435129; called by muse, mutect2, varscan2
- TEX10 | c.2724T>G p.H908Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV52444064; called by muse, mutect2
- TEX15 | c.3957G>T p.M1319I (on ENST00000256246; = p.M1702I on NM_001350162.2) | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV56348296; called by muse, mutect2
- TEX2 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1254560913, COSV51982613; called by muse, mutect2, varscan2
- TEX26 | c.674G>T p.R225M | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV66840096; called by muse, mutect2, varscan2
- TEX47 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51878499; called by muse, mutect2, varscan2
- TG | c.6109G>A p.E2037K | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV55081626; called by muse, mutect2
- TGM4 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56094644, COSV56096559; called by muse, mutect2, varscan2
- THEG | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs146622836; called by muse, mutect2, varscan2
- TIAM1 | c.3230C>A p.T1077N | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54558206; called by muse, mutect2, varscan2
- TKTL2 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54919682; called by muse, mutect2, varscan2
- TLE4 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV54634593, COSV99513132; called by muse, mutect2, varscan2
- TLR4 | c.2150C>A p.A717D (on ENST00000355622 / NM_138554.5; = p.A677D on NM_003266.4) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100842714, COSV62924197; called by muse, mutect2, varscan2
- TMA16 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62187811; called by muse, mutect2
- TMC3 | c.2113C>G p.R705G | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV63923593; called by muse, mutect2, varscan2
- TMEM11 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV100471918; called by muse, mutect2, varscan2
- TMEM131 | c.4954G>T p.G1652C | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV51778802, COSV99486903; called by muse, mutect2, varscan2
- TMEM132E | c.2614C>G p.P872A (on ENST00000321639; = p.P962A on NM_001304438.2) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as COSV58698191; called by muse, mutect2, varscan2
- TMEM141 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99264456; called by muse, mutect2, varscan2
- TMEM185A | c.423+1G>T p.X141_splice | Splice Site (SNP) | VAF 29/82 reads (35%) | catalogued as COSV57559913; called by muse, mutect2, varscan2
- TMEM200A | c.1204C>G p.R402G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.997); catalogued as rs146211569, COSV51654837, COSV51657942; called by muse, mutect2, varscan2
- TMPPE | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1253770943, COSV100257652; called by muse, mutect2, varscan2
- TMPRSS11B | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV60292953, COSV60293850; called by muse, mutect2, varscan2
- TMPRSS7 | c.2378C>A p.P793H (on ENST00000452346; = p.P667H on NM_001042575.2) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69981279; called by muse, mutect2, varscan2
- TMTC1 | c.542T>C p.L181P (on ENST00000539277 / NM_001193451.2; = p.L73P on NM_175861.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55485083; called by muse, mutect2, varscan2
- TMX3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs1475140298, COSV55185248; called by muse, mutect2, varscan2
- TNC | c.4964G>T p.R1655I | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.833); catalogued as COSV60786360; called by muse, mutect2, varscan2
- TNNI3K | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.285); catalogued as COSV53948174, COSV53949669; called by muse, mutect2, varscan2
- TNR | c.3689T>A p.M1230K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54894055; called by muse, mutect2
- TNR | c.3630G>T p.L1210= | Splice Region (SNP) | VAF 18/114 reads (16%) | catalogued as COSV54894077; called by muse, mutect2, varscan2
- TNRC6C | c.3368A>T p.Q1123L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56948054; called by muse, mutect2, varscan2
- TOM1L1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV61947554, COSV61948143; called by muse, mutect2, varscan2
- TOX2 | c.1349C>A p.S450* (on ENST00000358131 / NM_001098798.2; = p.S426* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV57888676; called by muse, mutect2, varscan2
- TPO | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150489706; called by muse, mutect2
- TRIM2 | c.1138G>T p.E380* (on ENST00000437508; = p.E407* on NM_015271.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV58635538; called by muse, mutect2, varscan2
- TRIP6 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV52342271; called by muse, mutect2, varscan2
- TRPM2 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV55971674; called by muse, mutect2
- TRPM4 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1246864602, COSV53264678; called by muse, mutect2, varscan2
- TRPM6 | c.5782G>A p.G1928R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62503258, COSV62512108; called by muse, mutect2, varscan2
- TRPM8 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61222559; called by muse, mutect2, varscan2
- TRPS1 | c.389G>T p.R130I (on ENST00000220888 / NM_001330599.2; = p.R143I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV55239281, COSV55247769; called by muse, varscan2
- TRRAP | c.2606G>T p.R869L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62847153; called by muse, mutect2, varscan2
- TSHR | c.341T>A p.L114* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99992641; called by muse, mutect2, varscan2
- TTC27 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs538191069, COSV100513492; called by muse, mutect2, varscan2
- TTLL5 | c.2245G>T p.A749S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.551); catalogued as COSV54036758; called by muse, mutect2, varscan2
- TTLL7 | c.949T>C p.C317R | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53085711; called by muse, mutect2, varscan2
- TTN | c.86854C>A p.H28952N (on ENST00000591111; = p.H21528N on NM_003319.4) | Missense Mutation (SNP) | VAF 42/196 reads (21%) | PolyPhen probably damaging (0.991); catalogued as COSV60149806; called by muse, mutect2, varscan2
- TTN | c.24967A>C p.K8323Q (on ENST00000591111; = p.K7396Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | PolyPhen probably damaging (0.991); catalogued as COSV60149837; called by muse, mutect2, varscan2
- TTN | c.11516A>T p.Q3839L (on ENST00000591111; = p.Q3793L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/176 reads (10%) | catalogued as COSV60149846; called by muse, mutect2, varscan2
- TUBGCP2 | c.1215-2A>T p.X405_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV53306244; called by muse, mutect2, varscan2
- UBE2A | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV60636824; called by muse, mutect2, varscan2
- UBE2K | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV54691073; called by muse, mutect2, varscan2
- UBN1 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV52169338; called by muse, mutect2, varscan2
324 further variants in this file (101 protein-altering or splice-affecting, 207 silent, 16 other) are not listed here.
